Somatic mutation profile of tumor specimen 0DAN65 from CCDI case PBBKGG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Atypical choroid plexus papilloma; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 0.5 years (200 days).
Specimen 0DAN65: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12f368ff-c990-4a5a-b501-ba0c3403cd0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAN5Y (Solid Tissue; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65966d7b-8db3-43c6-a3b1-3c2411b9c90b

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.999G>T p.Q333H | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65045505; called by muse, mutect2
- CFLAR | c.606+1026T>A | Intron (SNP) | VAF 11/334 reads (3%) | called by muse, mutect2
- SLC6A4 | c.-85C>T | 5'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs761797358; called by mutect2, varscan2
